Surgical pathology report (de-identified scan), TCGA case TCGA-L9-A743, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Candler, specimen TCGA-L9-A743-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]	ACCT #: [REDACTED]	LOC: [REDACTED]
REG DR: [REDACTED]	AGE/SX: /M	ROOM: [REDACTED]
	DOB: [REDACTED]	BED: [REDACTED]
	STATUS: [REDACTED]	

SPEC #: [REDACTED]	RECD: [REDACTED]	STATUS: [REDACTED]	
	COLL: [REDACTED]	TIME IN FORMALIN: [REDACTED]	hrs.
		COLD ISCHEMIA TIME: [REDACTED]	mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Squamous cell CA left upper lobe lung

Remarks:

- Specimen(s):
- A. Biopsy for 4R lymph node for frozen section
- B. Biopsy level 7 lymph node for frozen section
- C. Level 7 lymph node for permanent
- D. Left upper lobe with bronchial margin
- E. Level 5 lymph node
- F. Level 10 lymph node

MICROSCOPIC DIAGNOSIS

- A. R4 LYMPH NODE (BIOPSY): - NEGATIVE FOR METASTASIS
- B. LEVEL 7 LYMPH NODE (BIOPSY): - NEGATIVE FOR METASTASIS
- C. LEVEL 7 LYMPH NODE (BIOPSY): - NEGATIVE FOR METASTASIS
- D. LUNG, LEFT UPPER LOBE (LOBECTOMY):
- ADENOCARCINOMA, 4.5 CM GREATEST DIMENSION
- METASTATIC CARCINOMA IN 3 OF 5 PERIBRONCHIAL LYMPH NODES WITH EXTRANODAL EXTENSION
- VASCULAR INVASION PRESENT
- VISCERAL PLEURAL INVASION PRESENT
- SURGICAL MARGINS UNINVOLVED
- SEE COMMENT FOR SYNOPTIC REPORT
- E. LEVEL 5 LYMPH NODE (BIOPSY): - NEGATIVE FOR METASTASIS
- F. LEVEL 10 LYMPH NODE (BIOPSY): - METASTATIC CARCINOMA

ICD-O-3
Adenocarcinoma NOS
8140/3
Site @ Lung, upper lobe
034.1
JW 8/11/13

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - CAP APPROVED

Specimen:	Left upper lobe
Procedure:	Lobectomy
Specimen Integrity:	Intact

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #

PATIENT:

(Continued)

COMMENT(S)

(Continued)

Specimen Laterality: Left
Tumor Site: Upper lobe
Tumor Size: 4.5 cm in greatest dimension
Tumor Focality: Unifocal
Histologic Type: Adenocarcinoma
Histologic Grade: G3: poorly differentiated
Visceral Pleural Invasion: Present
Tumor Extension: Not applicable
Margins: Distance of invasive carcinoma from closest margin: 15 mm; parenchymal margin
Bronchial: Uninvolved by invasive carcinoma and carcinoma in situ
Vascular: Uninvolved by invasive carcinoma
Parenchymal: Uninvolved by invasive carcinoma
Treatment Effect: Not applicable
Lymph-Vascular Invasion: Present
Lymph Nodes Extranodal Extension: Present
Pathologic Staging: Primary Tumor: pT2a
Regional Lymph Nodes: pN1
Number examined: 10
Number involved: 4
Distant Metastasis: Not applicable

GROSS DESCRIPTION:

The specimen is received in the fresh state in two parts for frozen section evaluation.

- A. This is fragments of soft, tan and black lymph node measuring 8 mm in aggregate, totally examined by frozen section as block A1.
- B. This is fragments of soft, black lymph node measuring 8 mm in aggregate, totally examined by frozen section as block B1.
- C. This specimen is received in the fresh state from the operating room for permanent section evaluation and consists of fragments of soft, black lymph node measuring 1 cm in aggregate, totally submitted as block C1.
- D. This specimen is received in the fresh state from the operating room for evaluation of surgical margins and for tumor banking. requests evaluation of the specimen for bronchial margin and for a parenchymal margin staple line present on the specimen. The specimen consists of a left upper lobectomy specimen which measures 18 x 10 x 6 cm. Present centrally is an area of distorted visceral pleura with underlying palpable tumor. Blue ink is applied to the visceral pleural surface. Sections reveal a firm, partly necrotic tan tumor which measures 4.5 x 3.5 x 2.5 cm, located 1.5 cm from the parenchymal margin of concern to and 3 cm from the bronchial margin. Representative sections of the tumor are removed by aseptic technique and submitted for tumor banking. Three soft, black peribronchial lymph nodes are present measuring up to 1.5 cm in greatest dimension. The following sections are submitted:

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

- D1 - one peribronchial lymph node sectioned and totally submitted
- D2 - two peribronchial lymph nodes sectioned and totally submitted
- D3 - bronchial margins
- D4 - vascular margins
- D5 - two peribronchial lymph nodes bisected and totally submitted
- D6-9 - representative tumor with blue ink on visceral pleura
- D10 - representative lung

Two additional specimens are received in formalin.

E. This is multiple fragments of soft, black lymph node which in aggregate measure 2 x 2 x 0.4 cm. totally submitted as block E1.

F. This is fragments of soft, black lymph node measuring 1 x 1 x 0.3 cm. totally submitted as block F1.

INTRAOPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS:

- NO TUMOR SEEN

B. FROZEN SECTION DIAGNOSIS:

- NO TUMOR SEEN

D. IMMEDIATE GROSS EVALUATION LEFT UPPER LOBE:

- 4.5 CM TUMOR PRESENT 1.5 CM FROM PARENCHYMAL MARGIN AND 3.0 CM FROM BRONCHIAL MARGIN

PHOTO DOCUMENTATION

Image

Signed ____ (signature on file) ____

** END OF REPORT **

Criteria	hw 8/6/13	Yes	No
Prior Malignancy History	Prostate	✓	✓

Source: NCI Genomic Data Commons file 7fd14f12-f386-474f-bb99-e29b62e2ddce (TCGA-L9-A743.58EBD3CE-DB70-4A6C-A267-AEC8E50B6BD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).